Somatic mutation profile of tumor specimen MP2PRT-PANURD-TBP1-A (aliquot MP2PRT-PANURD-TBP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANURD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (747 days).
Specimen MP2PRT-PANURD-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cde4919a-ffab-4afb-b574-6942329ab5ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANURD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANURD-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cd30cc7-29ea-4c74-bde8-0e6031dccdd7

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 67/344 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs141435173; called by muse, mutect2, varscan2
- ARHGEF40 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 32/349 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as rs761052679; called by muse, mutect2
- DMRTB1 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 117/991 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs545617032; called by muse, mutect2
- KCNA2 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 25/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60369560; called by muse, mutect2
- ADAMTS20 | c.2731A>G p.I911V | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRL2 | c.706A>C p.T236P | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- IGHV2-26 | c.355_357del p.I119del | In Frame Del (DEL) | VAF 11/106 reads (10%) | called by pindel*, varscan2
- ZBTB10 | c.1706A>C p.Q569P | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AMER1 | c.228A>T p.G76= | Silent (SNP) | VAF 67/345 reads (19%) | catalogued as COSV57653801; called by muse, mutect2, varscan2
- CNGA4 | c.381G>A p.V127= | Silent (SNP) | VAF 20/600 reads (3%) | called by muse, mutect2
- ULK4 | c.3114A>G p.V1038= | Silent (SNP) | VAF 32/364 reads (9%) | called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins TCTTC | 3'Flank (INS) | VAF 29/100 reads (29%) | called by pindel, varscan2
